Gene-level copy-number profile of tumor specimen TCGA-XK-AAJR-01A from TCGA case TCGA-XK-AAJR, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.0 years (22,643 days).
Specimen TCGA-XK-AAJR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.1ebadd7d-f9b5-4593-9759-81f0541db272.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XK-AAJR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/135dfeca-fcf1-49a6-9f22-065cd259078a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 7,543; copy number 2: 52,177; copy number 4: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XK-AAJR-01A-11D-A41J-01): tumor purity 0.46, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:214,870,734–216,423,448, 13 genes: GAPDHP24, AC099563.1, AC099563.2, KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1.
- chr8:33,859,480–36,191,194, 17 genes: AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,163. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
